CPTAC case C3L-02165 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/319b7d38-2214-4efc-bc53-3d184a8053fe

Demographics
Sex at birth: male; Race: white; Year of birth: 1952; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 64.8 years (23,666 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R0; Days to last known disease status: 6 days; Days to last follow up: 6 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm (a second GDC size field records 6 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 14; Margin status: Indeterminate.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 6.

Other clinical attributes
- Weight: 80 kg; Height: 176 cm; BMI: 25.83; FEV1 before bronchodilator (% of reference): 89.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 24; Cigarettes per day: 20; Tobacco smoking onset year: 1992; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 30.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02165-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 980 mg; Time between clamping and freezing: 54 minutes; Time between excision and freezing: 26 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02165-21: Section location: Left Lower Lobe; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3L-02165-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 353 mg; Time between clamping and freezing: 63 minutes; Time between excision and freezing: 35 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02165-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
